Somatic mutation profile of tumor specimen TCGA-FS-A1ZU-06A (aliquot TCGA-FS-A1ZU-06A-12D-A196-08) from TCGA case TCGA-FS-A1ZU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.3 years (26,400 days).
Specimen TCGA-FS-A1ZU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55e8de5e-9135-45e5-8d51-b3fdfb991c1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZU-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZU-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ab1fe96-8ae8-4be8-b1e3-72b622f1e949

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 22/70 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1057519956, COSV55299564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.13057G>A p.A4353T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as rs375501382; called by muse, mutect2, varscan2
- C7orf31 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as rs1360307688, COSV52216782; called by muse, mutect2, varscan2
- CPEB1 | c.599G>A p.G200E (on ENST00000617958; = p.G140E on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.187); catalogued as rs1383859431, COSV55618255; called by muse, mutect2, varscan2
- ERICH3 | c.2069A>C p.K690T | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs1423733010, COSV58603903; called by muse, mutect2, varscan2
- FAM78B | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57976371; called by muse, mutect2, varscan2
- H4-16 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63761895; called by muse, mutect2, varscan2
- IMPG2 | c.497T>A p.M166K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.071); catalogued as COSV51976314; called by muse, mutect2, varscan2
- KCNN4 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs200755307, COSV99486916; called by muse, mutect2, varscan2
- KIAA1614 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775217655, COSV62552685; called by muse, mutect2, varscan2
- LILRB4 | c.706+2T>G p.X236_splice | Splice Site (SNP) | VAF 12/22 reads (55%) | catalogued as COSV54404091, COSV54404536; called by muse, varscan2
- MYO19 | c.275_276del p.E92Vfs*19 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1304435444; called by pindel, varscan2
- NDUFA4 | c.164A>T p.K55I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60011933; called by muse, mutect2, varscan2
- NOLC1 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV64180252; called by mutect2, varscan2
- PAPPA2 | c.4009C>A p.H1337N | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV62794742; called by muse, mutect2, varscan2
- PCDHB12 | c.2083G>C p.A695P | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV53395230; called by muse, mutect2, varscan2
- PCF11 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs1227470402, COSV53529748; called by muse, mutect2, varscan2
- PIK3R4 | c.3349G>A p.V1117M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV63240205; called by muse, mutect2, varscan2
- PITPNM2 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54899012; called by muse, mutect2, varscan2
- PKDREJ | c.4297A>G p.S1433G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV53548437; called by muse, mutect2, varscan2
- PKP1 | c.849C>T p.V283= | Splice Region (SNP) | VAF 12/92 reads (13%) | catalogued as COSV55820670; called by muse, mutect2
- PNN | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1354588068, COSV53765970; called by muse, mutect2, varscan2
- POLA2 | c.329T>A p.L110* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV55482197; called by muse, mutect2, varscan2
- RAC1 | c.276T>G p.N92K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV61822505, COSV61823666; called by muse, mutect2, varscan2
- SERPINI2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52985485; called by muse, mutect2
- SMAD6 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs776644944, COSV56594209; called by muse, mutect2, varscan2
- SNIP1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56166158; called by muse, mutect2, varscan2
- SNX33 | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV57913176; called by muse, mutect2, varscan2
- SSBP2 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57795782; called by muse, mutect2, varscan2
- TMC3 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV63922710; called by muse, mutect2, varscan2
- ZBTB26 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.088); catalogued as COSV65403053, COSV65403631; called by muse, mutect2, varscan2
- ZNF462 | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 183/324 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs748634199, COSV52935098; called by muse, mutect2, varscan2
- ZNF711 | c.2028G>T p.L676F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52152995; called by muse, mutect2, varscan2
- NOL8 | c.2498dup p.L834Afs*3 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- NPHP3 | c.327_328del p.L109Ffs*53 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- ASMT | c.432G>A p.T144= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as rs1178195909, COSV67109756; called by muse, mutect2
- BNIP5 | c.1632A>C p.A544= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV71325480; called by muse, mutect2, varscan2
- CSMD1 | c.4470C>T p.I1490= (on ENST00000520002; = p.I1489= on NM_033225.6) | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs777514021, COSV59306927; called by muse, varscan2
- CTSG | c.420G>A p.T140= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1452143795, COSV53535120; called by muse, mutect2, varscan2
- DLGAP2 | c.2262C>T p.V754= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs775703416, COSV70096854; called by muse, mutect2, varscan2
- KIF2B | c.1518C>T p.S506= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV52128893, COSV52129232; called by muse, mutect2, varscan2
- KLHL40 | c.981C>T p.G327= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1251409080, COSV55133865; called by muse, mutect2, varscan2
- RNF148 | c.186C>T p.F62= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs779498986, COSV57357971; called by muse, mutect2, varscan2
- RSBN1L | c.18C>T p.S6= | Silent (SNP) | VAF 54/65 reads (83%) | catalogued as rs1411086385, COSV58507552; called by muse, mutect2, varscan2
- SMARCA2 | c.4173C>T p.I1391= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs763381660, COSV56645855; called by muse, mutect2, varscan2
- TP63 | c.57C>A p.I19= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV53198309, COSV53202569; called by muse, mutect2, varscan2
- ZNF629 | c.1305C>T p.C435= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs780697625, COSV52698018; called by muse, mutect2, varscan2
- ITGB1 | c.2331+1259A>G | Intron (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.638G>A | RNA (SNP) | VAF 8/72 reads (11%) | catalogued as rs532390954, COSV55598765; called by mutect2, varscan2
